Gene-level copy-number profile of tumor specimen ALCH-AC6A-TTP1-A from ALCHEMIST case ALCH-AC6A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.8 years (23,674 days).
Specimen ALCH-AC6A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f2c5120e-2a61-4bfd-9968-94138378117c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AC6A-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/985b17c9-88ae-47da-9f63-65fb2a83e61e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 94; copy number 1: 7,542; copy number 2: 46,997; copy number 3: 3,183; copy number 4: 411; copy number 5: 170.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,487,246–3,487,627, 1 gene: AL512413.1.
- chr1:3,712,200–3,714,298, 1 gene (within-gene range 0–1): TP73-AS2.
- chr1:16,978,926–17,011,928, 3 genes (within-gene range 0–2): AL049569.1, ATP13A2, AL049569.3.
- chr1:223,947,605–223,950,416, 1 gene: CICP5.
- chr1:223,976,146–223,976,249, 1 gene: RNU6-1319P.
- chr5:473,236–480,884, 1 gene (within-gene range 0–1): SLC9A3-AS1.
- chr7:4,811,188–4,811,289, 1 gene (within-gene range 0–2): Y_RNA.
- chr7:102,433,106–102,464,863, 2 genes (within-gene range 0–2): ORAI2, ALKBH4.
- chr7:102,465,742–102,465,826, 1 gene (within-gene range 0–1): MIR5090.
- chr8:43,539,137–43,544,057, 3 genes: AC134698.5, CYP4F44P, AC134698.2.
- chr8:142,567,260–142,577,881, 1 gene: MROH4P.
- chr9:104,927,553–104,928,892, 1 gene (within-gene range 0–1): AL359182.1.
- chr9:134,379,411–134,379,472, 1 gene (within-gene range 0–1): MIR4669.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr11:832,887–842,529, 2 genes: CD151, POLR2L.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr15:21,328,380–21,951,323, 36 genes: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–3): OR4H6P.
- chr15:22,094,522–22,095,472, 1 gene (within-gene range 0–3): OR4N4.
- chr15:22,145,939–22,225,329, 7 genes: AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4, MIR1268A.
- chr15:25,172,635–25,204,438, 18 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19.
- chr19:5,784,832–5,791,225, 1 gene (within-gene range 0–1): DUS3L.
- chr21:44,300,051–44,339,402, 4 genes (within-gene range 0–2): PFKL, AP001062.3, CFAP410, AP001062.1.
- chr21:45,981,769–46,005,050, 1 gene: COL6A1.
- chr22:46,112,749–46,113,768, 3 genes (within-gene range 0–2): MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 170 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:62,260,338–69,390,870, 167 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:62,877,738–62,948,475, 3 genes, copy number 5: DIDO1, AL117379.1, GID8.

Autosomal genes at a single copy (total copy number 1): 7,542. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
